Somatic mutation profile of tumor specimen MP2PRT-PATCUP-TMP1-A (aliquot MP2PRT-PATCUP-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATCUP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,150 days).
Specimen MP2PRT-PATCUP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ad1d775-080e-46d1-a4e4-8cd57855752a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCUP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCUP-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c01c696-9203-4e8f-af46-40e7a00f8fa8

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH9 | c.1719C>A p.N573K | Missense Mutation (SNP) | VAF 81/356 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV50502353; called by muse, mutect2, varscan2
- CTAGE1 | c.1015A>T p.T339S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.061); catalogued as rs376583827; called by muse, mutect2, varscan2
- IRS1 | c.2585C>T p.S862F | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs896347997; called by muse, mutect2
- KCNC1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 64/477 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV99789377; called by muse, mutect2, varscan2
- PCDHB1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 130/312 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs782642827, COSV60630574; called by muse, mutect2, varscan2
- FLOT1 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 113/433 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR2A | c.1046G>A p.C349Y | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406868 del CCATTCACAGTGTTACAAGCCATAACAA | Missense Mutation (DEL) | VAF 29/62 reads (47%) | called by pindel, varscan2
- KIF17 | c.1334A>G p.Y445C | Missense Mutation (SNP) | VAF 126/301 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NEURL4 | c.1302_1303insGCCCGGCC p.H435Afs*30 | Frame Shift Ins (INS) | VAF 26/244 reads (11%) | called by mutect2, pindel
- YPEL3 | c.25_26insTCCCCCT p.T9Ifs*10 (on ENST00000398838 / NM_001145524.2; = p.T47Ifs*10 on NM_031477.5) | Frame Shift Ins (INS) | VAF 108/345 reads (31%) | called by mutect2, pindel*, varscan2
- ABCA2 | c.4359C>T p.V1453= (on ENST00000614293; = p.V1423= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 128/401 reads (32%) | catalogued as rs760297048; called by muse, mutect2, varscan2
- BRD4 | c.3552G>A p.P1184= | Silent (SNP) | VAF 99/285 reads (35%) | catalogued as rs748002758; called by muse, mutect2, varscan2
- RIPPLY2 | c.375C>T p.T125= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
